CCDI case PBCGDC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/39342121-af12-42ba-ac0c-32146326d23b

Demographics
Sex at birth: male.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 6.0 years (2,202 days).

Biospecimens (3 samples)
- Sample 0DRXE0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRXEA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DRXEM: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
